Gene-level copy-number profile of tumor specimen TCGA-2G-AAEW-01A from TCGA case TCGA-2G-AAEW, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Dead; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 31.0 years (11,325 days).
Specimen TCGA-2G-AAEW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.9c74aae8-d90f-4130-83ca-1d97a63eb8a4.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAEW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 359 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/78c9eb11-0432-42cd-84af-1ab02ae62b0a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 312; copy number 1: 2,389; copy number 2: 2,173; copy number 3: 16,977; copy number 4: 29,817; copy number 5: 7,623; copy number 6: 876; copy number 7: 1; copy number 10: 95; copy number 11: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAEW-01A-11D-A42X-01): tumor purity 0.42, ploidy 3.77, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 312 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr5:178,840,097–178,841,134, 1 gene: AC126915.1.
- chr15:76,586,647–76,586,691, 1 gene: MIR3713.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.
- chr18:23,134,564–47,176,364, 307 genes (within-gene range 0–3) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 96 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,537,184–68,616,137, 3 genes, copy number 10 (within-gene range 3–10): UGT2B17, AC147055.2, AC147055.4.
- chr14:105,764,503–106,318,236, 92 genes, copy number 10 (broad region; genes not listed).
- chr19:33,283,978–33,285,739, 1 gene, copy number 11: AC008738.6.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
